Gene-level copy-number profile of tumor specimen TCGA-23-2072-01A from TCGA case TCGA-23-2072, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 58.9 years (21,523 days).
Specimen TCGA-23-2072-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.71165841-5984-4594-a722-cefc62ccf65f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-2072-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/76da44d9-d9c5-4b3b-b33e-c90b300deb45

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 4; copy number 2: 2,824; copy number 3: 669; copy number 4: 24,539; copy number 5: 1,734; copy number 6: 20,688; copy number 7: 412; copy number 8: 8,169; copy number 9: 44; copy number 10: 356; copy number 11: 271; copy number 12: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-2072-01A-01D-0663-01): tumor purity 0.81, ploidy 2.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:30,970,984–30,999,911, 1 gene (within-gene range 0–6): RNF135.
- chr17:30,978,610–31,713,853, 27 genes: AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724, MIR193A, AC003101.2, RNU6ATAC7P, AC003101.1, MIR4725, MIR365B, AC007923.3, AC007923.2, RNU6-1134P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 746 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,994,794–26,733,420, 22 genes, copy number 9: UQCRHP2, TRMT112P6, RAB10, RNU6-942P, RPS2P15, EMP2P1, SMARCE1P6, AC011742.1, PPIL1P1, GAREM2, HADHA, HADHB, AC010896.1, ADGRF3, SELENOI, DRC1, OTOF, FAM166C, CIB4, AC015977.1, RPL37P11, KCNK3.
- chr3:36,616,006–37,861,802, 32 genes, copy number 10 (within-gene range 6–10): NBPF21P, RN7SKP227, DCLK3, HSPD1P6, LINC02033, AC105749.1, TRANK1, AC011816.1, RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1, MLH1, RPL29P11, LRRFIP2, Y_RNA, UBE2D3P2, RNU6-1301P, UBE2FP1, AC126118.1, AC097359.1, AC097359.3, AC097359.2, GOLGA4, TCEA1P2, RNA5SP129, C3orf35, ITGA9, RNU7-73P, ITGA9-AS1, RPL21P135, NDUFAF4P3.
- chr3:124,965,710–126,517,773, 54 genes, copy number 10: HEG1, RNA5SP137, AC117488.1, SLC12A8, RNU6-230P, MIR5092, ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11, AF186996.3, AF186996.2, OR7E130P, OR7E29P, OR7E93P, OR7E53P, OR7E97P, AF186996.1, AC092902.4, AC092902.5, AC092902.2, AC092902.1, MIR548I1, RPS3AP14, AC092902.6, SNRPCP11, LINC02614, ENPP7P4, AC092903.2, FAM86JP, ALG1L, AC092903.1, ROPN1B, SLC41A3, AC117422.1, AC079848.1, ALDH1L1, ALDH1L1-AS1, RNU1-30P, ALDH1L1-AS2, AC079848.2, AC016924.1, AC063919.1, AC063919.2, KLF15, CCDC37-DT, CFAP100, AC073439.1, ZXDC, UROC1.
- chr3:168,249,522–169,869,935, 27 genes, copy number 12 (within-gene range 8–12): EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31.
- chr3:194,005,259–198,222,513, 157 genes, copy number 10 (broad region; genes not listed).
- chr7:66,205,317–68,119,209, 50 genes, copy number 10: TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57.
- chr7:131,661,952–131,948,953, 7 genes, copy number 11: EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1.
- chr8:37,405,439–37,844,896, 16 genes, copy number 9: AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2.
- chr8:39,934,614–40,901,854, 11 genes, copy number 10 (within-gene range 4–10): IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4, AC048387.1.
- chr10:59,650,761–59,960,913, 4 genes, copy number 9 (within-gene range 5–9): SLC16A9, MRLN, CCDC6, LINC01553.
- chr10:60,050,668–60,081,854, 2 genes, copy number 9: AL592430.1, Y_RNA.
- chr13:113,105,788–114,337,626, 48 genes, copy number 12: F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr19:27,638,483–29,841,818, 52 genes, copy number 10: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2.
- chr22:20,110,821–23,387,731, 264 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
